Somatic mutation profile of tumor specimen TCGA-E7-A3X6-01A (aliquot TCGA-E7-A3X6-01A-12D-A22Z-08) from TCGA case TCGA-E7-A3X6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 70.0 years (25,584 days).
Specimen TCGA-E7-A3X6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e96253be-9f74-4895-952f-5fb17662ce12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A3X6-10A (Blood Derived Normal), aliquot TCGA-E7-A3X6-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd16bee2-ffa3-4484-aed7-91109ef868f1

The open-access MAF lists 114 somatic variants for this specimen: 82 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 29, Nonsense Mutation 6, Intron 2, 5'Flank 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNC3 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894699, CM061075, COSV65387781; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1223G>C p.R408T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52707258; called by muse, mutect2, varscan2
- ACTG1 | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV59510778; called by muse, mutect2, varscan2
- ADAMTS10 | c.1034T>C p.I345T | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54355717; called by muse, mutect2, varscan2
- AHNAK2 | c.10147G>A p.E3383K | Missense Mutation (SNP) | VAF 99/331 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.951); catalogued as rs374841889; called by muse, mutect2, varscan2
- ARHGEF35 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.12); catalogued as COSV100967768; called by muse, mutect2, varscan2
- ASB4 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV57945785; called by muse, mutect2, varscan2
- ASCC2 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV57074329; called by muse, mutect2, varscan2
- BSPRY | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.647); catalogued as rs778078570, COSV53057393; called by muse, mutect2, varscan2
- CAPRIN1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766999764, COSV58220258; called by muse, mutect2, varscan2
- CASR | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV56133872; called by muse, mutect2, varscan2
- CHD1L | c.1366C>A p.H456N | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63614309; called by muse, mutect2, varscan2
- CNTROB | c.1192G>T p.A398S | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.687); catalogued as rs756011585, COSV66608383, COSV66609526; called by muse, mutect2, varscan2
- COL27A1 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV61927080; called by muse, mutect2, varscan2
- CORO1C | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV54596490; called by muse, mutect2, varscan2
- DNAH2 | c.7656C>G p.I2552M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66720689; called by muse, mutect2, varscan2
- DNAJC16 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.864); catalogued as rs764526260, COSV65448702; called by muse, varscan2
- DNAJC16 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV65448707; called by muse, mutect2, varscan2
- EPG5 | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56350970; called by muse, mutect2, varscan2
- ERN2 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs768661196, COSV56834424; called by muse, mutect2, varscan2
- FBXO34 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775235375, COSV58254869; called by muse, mutect2, varscan2
- GABRA4 | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.679); catalogued as COSV51929312; called by muse, mutect2, varscan2
- HEPACAM2 | c.216A>T p.R72S (on ENST00000394468 / NM_001039372.4; = p.R60S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV59060962; called by muse, mutect2, varscan2
- HMCN1 | c.13667G>A p.C4556Y | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54907055; called by muse, mutect2, varscan2
- IGSF9B | c.3673C>G p.R1225G | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV58068700, COSV58069177; called by muse, mutect2, varscan2
- IKZF2 | c.1439T>C p.F480S | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59579482; called by muse, mutect2, varscan2
- IRX6 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV51860791; called by muse, mutect2, varscan2
- ITGAL | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.186); catalogued as COSV63322611, COSV99050720; called by muse, mutect2, varscan2
- KIF2B | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as rs543871191, COSV52128303; called by muse, mutect2, varscan2
- LMTK2 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.255); catalogued as COSV51997315; called by muse, mutect2, varscan2
- LRRN1 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV60014287; called by muse, mutect2, varscan2
- LUZP1 | c.1961G>C p.R654T | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as COSV56501979; called by muse, varscan2
- LUZP1 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV56501990, COSV56505977; called by muse, varscan2
- MAP4K1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs868330468, COSV67710843; called by muse, mutect2, varscan2
- MED29 | c.285G>C p.L95F (on ENST00000615911; = p.L74F on NM_017592.4) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV55393213, COSV99655936; called by muse, mutect2, varscan2
- MTMR11 | c.1178C>T p.S393L (on ENST00000439741 / NM_001145862.2; = p.S321L on NM_181873.3) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs782655361, COSV54965714; called by muse, mutect2, varscan2
- NCKAP5 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.814); catalogued as COSV58448909; called by muse, mutect2, varscan2
- NFATC2 | c.1909A>G p.M637V | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.728); catalogued as COSV65356952; called by muse, mutect2, varscan2
- NPLOC4 | c.1561C>G p.L521V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV58616003; called by muse, mutect2, varscan2
- NUDT15 | c.102G>C p.R34S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51642364; called by muse, mutect2, varscan2
- OR51D1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62914298; called by muse, mutect2, varscan2
- OR51D1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV62914302, COSV62914974; called by muse, mutect2, varscan2
- OR5H14 | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV101454086, COSV71194076; called by muse, varscan2
- OR6V1 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV69237340; called by muse, mutect2, varscan2
- PCNX3 | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV58420115; called by muse, mutect2, varscan2
- PNMA8B | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV66536777; called by muse, mutect2, varscan2
- POLD2 | c.281T>A p.V94E | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV56258582; called by muse, mutect2, varscan2
- PSEN1 | c.1158C>A p.F386L | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555358095, CM144211, COSV56194907; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRU | c.4093G>A p.D1365N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as rs1316823043; called by muse, mutect2
- RASA1 | c.2074C>G p.L692V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV57196672; called by muse, mutect2, varscan2
- RBM26 | c.1924C>G p.P642A (on ENST00000438737 / NM_001366735.2; = p.P639A on NM_022118.5) | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV57391241; called by muse, mutect2
- RPL4 | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57180759; called by muse, mutect2, varscan2
- RSPH1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV52319769; called by muse, mutect2, varscan2
- SHANK2 | c.3571G>A p.A1191T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV53584739; called by muse, mutect2, varscan2
- SLC19A1 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60754569, COSV60755283; called by muse, mutect2, varscan2
- SMARCC1 | c.1801C>G p.L601V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs771918475, COSV54381837; called by muse, varscan2
- SMG5 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as COSV62435754, COSV99054320; called by muse, mutect2, varscan2
- SOS2 | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV53568759; called by muse, mutect2, varscan2
- SPTAN1 | c.4423G>A p.D1475N | Missense Mutation (SNP) | VAF 87/155 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs1470406753, COSV63987639; called by muse, varscan2
- SPTAN1 | c.4624G>A p.E1542K | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.957); catalogued as rs1426441877, COSV63987653; called by muse, varscan2
- SPTAN1 | c.4690G>A p.E1564K | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV100823159, COSV63987657; called by muse, varscan2
- SRMS | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV53921025; called by muse, mutect2, varscan2
- TCF25 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54528966; called by muse, mutect2, varscan2
- THOC5 | c.1253A>G p.N418S | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182268471, COSV63799127; called by muse, mutect2, varscan2
- TM9SF2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1484119268, COSV63480891; called by muse, mutect2, varscan2
- TPM1 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.58); catalogued as COSV51262074; called by muse, mutect2, varscan2
- TPSG1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs747734341, COSV52354990; called by muse, varscan2
- TRAF3IP3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748662932, COSV50553698; called by muse, mutect2, varscan2
- TTN | c.101980G>A p.D33994N (on ENST00000591111; = p.D26570N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | PolyPhen benign (0.157); catalogued as COSV60114776; called by muse, mutect2, varscan2
- TTN | c.75361G>A p.E25121K (on ENST00000591111; = p.E17697K on NM_003319.4) | Missense Mutation (SNP) | VAF 78/275 reads (28%) | PolyPhen benign (0.361); catalogued as COSV60114824; called by muse, mutect2, varscan2
- ZNF492 | c.1151A>C p.K384T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV71762168; called by muse, mutect2, varscan2
- ZNF543 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.018); catalogued as COSV58627682; called by muse, mutect2, varscan2
- ZP4 | c.179A>C p.N60T | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV63912274; called by muse, mutect2, varscan2
- ACTR8 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ASXL2 | c.683C>G p.S228* | Nonsense Mutation (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- CAPRIN2 | c.2686C>T p.Q896* | Nonsense Mutation (SNP) | VAF 90/246 reads (37%) | called by muse, mutect2, varscan2
- CCDC9B | c.700dup p.D234Gfs*26 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- LILRA4 | c.197C>G p.S66* | Nonsense Mutation (SNP) | VAF 43/162 reads (27%) | called by muse, mutect2, varscan2
- PCDHB1 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 54/102 reads (53%) | called by muse, mutect2, varscan2
- PHOSPHO1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SEMA4B | c.2242del p.L748* | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- WAC | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- ABCA9 | c.4755C>A p.L1585= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV60626075; called by muse, mutect2, varscan2
- APOBEC3H | c.453C>T p.H151= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs578208861, COSV62378808; called by muse, mutect2, varscan2
- ARHGEF10L | c.813C>T p.F271= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV51434048; called by muse, mutect2, varscan2
- AUTS2 | c.3156C>T p.I1052= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV61401132; called by muse, mutect2, varscan2
- CAPRIN1 | c.450T>C p.L150= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs140627436; called by muse, mutect2, varscan2
- CASZ1 | c.2118G>A p.P706= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs748237845, COSV59736646; called by muse, mutect2, varscan2
- CDH3 | c.1065C>T p.D355= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs766592847, COSV50559823; called by muse, mutect2, varscan2
- CYB5B | c.72C>T p.V24= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV57174743; called by muse, mutect2, varscan2
- DAPK3 | c.1227C>T p.L409= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV56663388; called by muse, mutect2, varscan2
- EEF1A1 | c.21T>C p.H7= | Silent (SNP) | VAF 32/88 reads (36%) | called by muse, varscan2
- EPG5 | c.699G>C p.V233= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as COSV56344404, COSV56350961, COSV56356769; called by muse, mutect2, varscan2
- IL17RC | c.1623C>T p.L541= (on ENST00000295981 / NM_153461.4; = p.L455= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as rs1298744281, COSV55973529; called by muse, mutect2, varscan2
- IP6K2 | c.15C>T p.F5= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV60794027; called by muse, mutect2
- KCNB1 | c.237C>T p.D79= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV65566739; called by muse, mutect2, varscan2
- KMT2E | c.1521G>A p.Q507= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV57574359; called by muse, mutect2, varscan2
- MSH5 | c.660G>A p.V220= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV65209969; called by muse, mutect2, varscan2
- PAQR9 | c.969C>T p.Y323= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as rs1470569527, COSV61418363; called by muse, mutect2
- PIP4P1 | c.276C>T p.N92= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as rs150985847; called by muse, mutect2, varscan2
- PLXND1 | c.1890C>G p.L630= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV60714683; called by muse, mutect2, varscan2
- RNPEPL1 | c.1308G>T p.L436= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as COSV54372940; called by muse, mutect2, varscan2
- RSC1A1 | c.156T>C p.A52= | Silent (SNP) | VAF 160/352 reads (45%) | catalogued as COSV60779972; called by muse, mutect2, varscan2
- RWDD2B | c.420C>T p.F140= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs1331458430, COSV54501620; called by muse, mutect2, varscan2
- SNX9 | c.759G>C p.V253= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV67584613; called by muse, mutect2, varscan2
- SPTAN1 | c.5142G>A p.L1714= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV63987674; called by muse, varscan2
- TMEM54 | c.90G>C p.V30= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV61275884; called by muse, varscan2
- TMEM54 | c.24G>A p.L8= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV61275468, COSV61275897; called by muse, varscan2
- WDR64 | c.2730C>G p.L910= | Silent (SNP) | VAF 83/193 reads (43%) | catalogued as COSV63796744; called by muse, mutect2, varscan2
- WDR83 | c.141G>A p.K47= | Silent (SNP) | VAF 40/139 reads (29%) | catalogued as COSV54418530; called by muse, mutect2, varscan2
- ZNF292 | c.3990C>T p.F1330= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1386372801, COSV60540600; called by muse, mutect2, varscan2
- RCC1 | c.-261-705_-261-704dup | Intron (INS) | VAF 44/212 reads (21%) | called by mutect2, pindel, varscan2
- ST20-MTHFS | c.-12+376C>A | Intron (SNP) | VAF 8/19 reads (42%) | catalogued as COSV101530528; called by muse, mutect2
- TTI2 | chr8:33513557 T>A | 5'Flank (SNP) | VAF 40/75 reads (53%) | catalogued as rs1242662879, COSV62452325; called by muse, mutect2, varscan2
